Gene-level copy-number profile of tumor specimen TCGA-AX-A3G1-01A from TCGA case TCGA-AX-A3G1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 85.0 years (31,037 days).
Specimen TCGA-AX-A3G1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.3c676f76-70f3-4036-87ba-06a4467e951f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A3G1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5dde5d0b-84df-4ef4-84db-edbee06cbf9e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 18; copy number 2: 16,267; copy number 3: 13,039; copy number 4: 23,434; copy number 5: 4,720; copy number 6: 1,486; copy number 7: 478; copy number 8: 216; copy number 9: 140; copy number 10: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A3G1-01A-11D-A227-01): tumor purity 0.73, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,817,928–88,259,372, 9 genes (within-gene range 0–2): CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 146 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:130,827,406–130,837,135, 1 gene, copy number 10 (within-gene range 6–10): SMLR1.
- chr11:126,423,358–127,003,460, 3 genes, copy number 10 (within-gene range 7–10): KIRREL3, KIRREL3-AS1, AP001783.1.
- chr11:133,297,189–133,366,080, 2 genes, copy number 10: AP003972.1, OPCML-IT1.
- chr19:20,295,089–23,291,017, 140 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
